Gene-level copy-number profile of tumor specimen TCGA-FP-A8CX-01A from TCGA case TCGA-FP-A8CX, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.2 years (22,000 days).
Specimen TCGA-FP-A8CX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.d264f1e4-3f12-4350-b213-65a217471b17.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FP-A8CX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c98ddf16-b408-4da2-af2d-7b5cb23c73ca

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1,008; copy number 2: 13,879; copy number 3: 28,170; copy number 4: 5,997; copy number 5: 6,953; copy number 6: 3,407; copy number 7: 220; copy number 8: 14; copy number 11: 1; copy number 35: 46; copy number 38: 21; copy number 43: 1; copy number 45: 8; copy number 47: 2; copy number 58: 8; copy number 71: 7; copy number 72: 5; copy number 78: 1; copy number 79: 11; copy number 81: 9; copy number 82: 23; copy number 95: 1; copy number 106: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FP-A8CX-01A-11D-A363-01): tumor purity 0.27, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 393 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:169,083,499–169,663,775, 1 gene, copy number 95 (within-gene range 4–95): MECOM.
- chr3:169,613,510–169,812,986, 12 genes, copy number 11–79 (within-gene range 4–79): AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2.
- chr3:169,966,635–169,998,373, 1 gene, copy number 78 (within-gene range 3–78): SEC62.
- chr3:170,222,424–170,908,644, 17 genes, copy number 47–106 (within-gene range 3–106): PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3, AC026316.5, AC026316.2, RPL22L1, EIF5A2.
- chr12:67,929,235–68,253,604, 9 genes, copy number 81: LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22.
- chr12:68,805,011–69,584,823, 23 genes, copy number 82: AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2.
- chr17:37,798,894–37,940,790, 5 genes, copy number 72: AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA.
- chr17:39,665,349–39,747,291, 7 genes, copy number 71: TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr17:39,953,263–40,093,867, 8 genes, copy number 58 (within-gene range 2–58): GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA.
- chr17:58,982,638–64,954,177, 220 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr19:43,474,954–43,754,962, 18 genes, copy number 35 (within-gene range 4–35): PHLDB3, ETHE1, ZNF575, XRCC1, L34079.2, L34079.1, L34079.3, PINLYP, IRGQ, ZNF576, SRRM5, ZNF428, CADM4, PLAUR, RN7SL368P, AC005622.1, IRGC, SMG9.
- chr19:43,785,874–43,827,206, 1 gene, copy number 45 (within-gene range 4–45): LYPD5.
- chr19:43,827,321–43,967,709, 8 genes, copy number 43–45 (within-gene range 4–45): ZNF283, ZNF404, AC006213.6, AC006213.2, AC006213.7, AC006213.3, ZNF45, ZNF221.
- chr19:44,382,298–44,909,393, 28 genes, copy number 35: ZNF285, AC245748.2, ZNF229, ZNF285B, ZNF180, CEACAM20, AC245748.3, CEACAM22P, AC243964.1, IGSF23, AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, AC092306.1, BCAM, NECTIN2, AC011481.2, TOMM40, APOE.
- chr19:45,769,709–46,196,218, 21 genes, copy number 38 (within-gene range 3–38): DMPK, AC011530.1, DMWD, RSPH6A, SYMPK, AC092301.1, FOXA3, IRF2BP1, MYPOP, NANOS2, NOVA2, CCDC61, MIR769, PGLYRP1, AC007785.3, IGFL4, AC007785.1, AC007785.2, IGFL3, TGIF1P1, IGFL2.
- chr20:15,552,157–16,770,062, 14 genes, copy number 8 (within-gene range 5–8): AL121584.1, ENSAP1, AL079338.1, AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR.

Autosomal genes at a single copy (total copy number 1): 274. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
